Somatic mutation profile of tumor specimen TCGA-AB-2927-03A (aliquot TCGA-AB-2927-03A-01W-0755-09) from TCGA case TCGA-AB-2927, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 88.5 years (32,326 days).
Specimen TCGA-AB-2927-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b64eda5-ea30-4cc4-98ea-624a2678ef56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2927-11A (Solid Tissue Normal), aliquot TCGA-AB-2927-11A-01W-0755-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/925c1716-d693-4229-84a8-ec46dea88a01

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.405G>T p.R135S (on ENST00000344691 / NM_001001890.3; = p.R162S on NM_001754.5) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519749, COSV100277991, COSV55879245; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKR7A2 | c.890G>C p.R297P | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV52515602, COSV99352123; called by muse, mutect2, varscan2
- AL031777.2 | c.484A>T p.R162* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV61912585; called by muse, mutect2, varscan2
- ASXL1 | c.1720-1G>T p.X574_splice | Splice Site (SNP) | VAF 18/55 reads (33%) | catalogued as rs1254271466, COSV100040440, COSV60124780; called by muse, mutect2, varscan2
- CHST6 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779619694, COSV100178516; called by muse, mutect2, varscan2
- CXorf58 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 63/189 reads (33%) | catalogued as rs771619651, COSV64858189; called by muse, mutect2, varscan2
- DIS3 | c.1999A>G p.M667V | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100899945, COSV66707375; called by muse, mutect2, varscan2
- ITGAD | c.2522T>C p.L841P | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.151); catalogued as COSV101210537; called by muse, varscan2
- LINC02210-CRHR1 | c.163A>G p.M55V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99523914; called by muse, mutect2
- MMD2 | c.564C>G p.C188W (on ENST00000404774 / NM_001100600.2; = p.C164W on NM_198403.4) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV101287081; called by muse, mutect2
- PGAP3 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as rs369922079; called by muse, varscan2
- SH2B3 | c.1313T>A p.L438H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57985558; called by muse, mutect2, varscan2
- SLFNL1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs779945577, COSV57234289; called by muse, mutect2, varscan2
- TTN | c.41442T>G p.D13814E (on ENST00000591111; = p.D6390E on NM_003319.4) | Missense Mutation (SNP) | VAF 85/221 reads (38%) | PolyPhen benign (0.01); catalogued as COSV100622053; called by muse, mutect2, varscan2
- SUMO2 | c.200_201insTA p.N68Tfs*62 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, varscan2
- TCF4 | c.1825dup p.Q609Pfs*98 | Frame Shift Ins (INS) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- BRINP1 | c.1122C>T p.P374= | Silent (SNP) | VAF 28/105 reads (27%) | called by mutect2, varscan2
- DAGLA | c.1192C>A p.R398= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV57197477, COSV99944572; called by muse, mutect2, varscan2
- PRELP | c.558C>A p.I186= | Silent (SNP) | VAF 109/275 reads (40%) | catalogued as COSV100557905; called by muse, mutect2, varscan2
- PRKD1 | c.1839C>T p.I613= | Silent (SNP) | VAF 91/285 reads (32%) | catalogued as COSV100121131; called by muse, mutect2, varscan2
